Surgical pathology report (de-identified scan), TCGA case TCGA-44-8120, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-8120-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]
[REDACTED]
Phone [REDACTED]

Final Surgical Pathology Report

Procedure: [REDACTED]

Diagnosis

- A. Lymph nodes, level XI, resection:
Negative for malignancy.
- B. Lymph nodes, level X, resection:
Negative for malignancy.
- C. Lung, right upper lobectomy:
Invasive moderately differentiated adenocarcinoma.
Tumor extends into the visceral pleural surface.
Bronchial and vascular margins of resection are free of tumor.
- D. Lymph nodes, level R II, resection:
Negative for malignancy.
- E. Lymph nodes, level R IV, resection:
Negative for malignancy.
- F. Lymph nodes, level VII, resection:
Negative for malignancy.

Microscopic Description:

Histologic type: Adenocarcinoma.
Histologic grade: Moderately differentiated.
Primary tumor (pT): Tumor measures maximally 2.6 cm in diameter and has
extended into the visceral pleural surface (pT2a).
Margins of resection: Bronchial and vascular margins are negative for
tumor.
Direct extension of tumor: Absent.
Venous (large vessel) invasion: Negative.
Arterial (large vessel) invasion: Negative.
Lymphatic (small vessel) invasion: Negative.
Regional lymph nodes (pN): All of the sampled mediastinal lymph nodes
are negative for metastatic carcinoma (pN0).
Distant metastasis (pM): pMx.

Specimen

- A. Level XI
- B. Level X
- C. Right upper lobe
- D. R 2
- E. R 4
- F. Level 7

Clinical Information
Lung cancer

[page 2 of 2]
Gross Description

A. Received unfixed, labeled level XI, is a fragmented, black, 1.2 x 0.6 x 0.5 cm nodal fragment, entirely submitted in one block.

B. Received unfixed, labeled level X, is a fragmented, black, 1.3 x 0.9 x 0.5 cm nodal fragment, entirely submitted in one block.

C. Received unfixed for tissue procurement, labeled right upper lobe, is a 164 g, 13 x 8 x 3.5 cm right upper lobectomy specimen. There is a 2.5 x 2.5 cm area with central puckering on the pleural surface, with an underlying tumor that is 2.6 x 2.5 x 2.0 cm. It has an irregular border and a gray-white to tan cut surface, with incorporated anthracotic pigment. The tumor does not appear to be arising from the nearby bronchi, and the bronchial margin is at least 2.5 cm from the tumor. No other tumors are identified. A representative portion of tumor and normal tissue submitted for tissue procurement. Representative sections as follows: 1 Bronchial and vascular margins; 2-4 tumor to pleural surf 5 tumor to closest stapled margin; 6 uninvolved lung tissue.

D. Received fresh labeled "R 2" are 6 fragmented white-pink to gray-black tissues ranging from 0.3-1.4 cm in greatest dimension. Summary: 1 - 5 tissues; 2 - 1 tissue

E. Received fresh labeled 4" are 5 soft tan-gray-pink tissues ranging from 0.3-1.0 cm.

F. Received fresh labeled "level VII" are 3 slightly rubbery tan-pink gray-black tissues ranging from 0.7-2.5 cm in greatest dimension.

Summary: 1 - 2 tissues; 2 - 1 bisected tissue

Source: NCI Genomic Data Commons file 6215d392-5136-4ab2-9623-e33265f85c77 (TCGA-44-8120.6996D5EB-BDFD-4B9B-9517-40C28E439834.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).